Gene-level copy-number profile of tumor specimen TCGA-04-1638-01A from TCGA case TCGA-04-1638, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 57.5 years (20,987 days).
Specimen TCGA-04-1638-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.e6262f58-9f82-48e5-958a-5762789f35e6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-04-1638-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fca9f94c-13c2-46c1-96ca-4e1d3e4512a8

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 1: 44; copy number 2: 17,712; copy number 3: 9,405; copy number 4: 28,202; copy number 5: 1,539; copy number 6: 2,638; copy number 7: 22; copy number 8: 18; copy number 9: 47; copy number 12: 22; copy number 15: 29; copy number 17: 82; copy number 20: 38.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-04-1638-01A-01D-0577-01): tumor purity 0.92, ploidy 3.47, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:13,843,133–14,658,821, 18 genes (within-gene range 0–2): CYP4F29P, SNX18P13, ANKRD20A11P, RHOT1P2, RNU6-954P, NF1P3, PPP6R2P1, FRG2MP, AP001347.1, ANKRD20A18P, RNA5SP488, AP001347.2, LIPI, ERLEC1P1, RBM11, ABCC13, HSPA13, SAMSN1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 218 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:69,051,363–69,112,987, 1 gene, copy number 20 (within-gene range 4–20): UGT2B7.
- chr4:69,125,274–73,871,308, 88 genes, copy number 12–20 (broad region; genes not listed).
- chr8:1,565,509–1,801,711, 6 genes, copy number 9: DLGAP2-AS1, AC100810.6, AC100810.2, CLN8, AC100810.3, AC100810.1.
- chr8:1,801,125–1,817,307, 3 genes, copy number 9: MIR3674, AC100810.7, MIR596.
- chr12:54,549,601–56,636,816, 120 genes, copy number 9–17 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 44. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
